Somatic mutation profile of tumor specimen 0DN51S from CCDI case PBCBHT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Larynx, NOS; Age at diagnosis: 5.2 years (1,910 days).
Specimen 0DN51S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a816593-048a-49ef-88fb-bc90f594eb2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN51K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e412343c-14f2-4397-b5fa-99efa86ec3cd

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 3, 5'UTR 2, In Frame Del 2, Intron 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH1A | c.174G>C p.M58I | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52925319; called by muse, mutect2, varscan2
- APC | c.7880C>T p.S2627F | Missense Mutation (SNP) | VAF 81/655 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs767337020, COSV57362503; called by muse, mutect2, varscan2
- BAZ2A | c.2459T>C p.M820T | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs1206844933; called by mutect2, varscan2
- CPAMD8 | c.614C>G p.P205R (on ENST00000651564; = p.P158R on NM_015692.5) | Missense Mutation (SNP) | VAF 47/383 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52240125; called by muse, mutect2
- DCK | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1423286703; called by muse, mutect2
- LTBP4 | c.768_785del p.R260_A265del (on ENST00000308370 / NM_001042544.1; = p.R223_A228del on NM_003573.2) | In Frame Del (DEL) | VAF 14/75 reads (19%) | catalogued as rs780900225; called by mutect2, varscan2
- LYST | c.10048G>A p.V3350M | Missense Mutation (SNP) | VAF 101/840 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451628268; called by muse, mutect2, varscan2
- PRICKLE1 | c.2369G>T p.R790I | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV58206664; called by muse, mutect2, varscan2
- RXRB | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765621405; called by muse, mutect2, varscan2
- TAB2 | c.964C>G p.R322G | Missense Mutation (SNP) | VAF 43/397 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs1034268466; called by muse, mutect2, varscan2
- TYRO3 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs775142130; called by muse, mutect2, varscan2
- ZNF655 | c.920G>A p.S307N | Missense Mutation (SNP) | VAF 31/553 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1204475933, COSV99402243; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 20/676 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- C8orf76 | c.802_804del p.F268del | In Frame Del (DEL) | VAF 41/399 reads (10%) | called by mutect2, varscan2
- CP | c.2642C>T p.S881L | Missense Mutation (SNP) | VAF 32/767 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DTNA | c.604-2A>G p.X202_splice | Splice Site (SNP) | VAF 46/452 reads (10%) | called by muse, mutect2
- HPSE2 | c.1477G>T p.V493F | Missense Mutation (SNP) | VAF 234/414 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNJ6 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LILRA4 | c.1442C>A p.A481E | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MORC4 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, varscan2
- OR52D1 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- OVGP1 | c.730A>T p.N244Y | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PCDH15 | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ROS1 | c.3307G>T p.A1103S | Missense Mutation (SNP) | VAF 363/604 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC8A3 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TBC1D32 | c.2679G>T p.K893N | Missense Mutation (SNP) | VAF 220/503 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.302); called by mutect2, varscan2
- UTP4 | c.1812C>A p.F604L | Missense Mutation (SNP) | VAF 43/647 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- ZSCAN18 | c.921G>C p.E307D | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, varscan2
- CAND1 | c.3093T>C p.N1031= | Silent (SNP) | VAF 130/735 reads (18%) | catalogued as rs1245398864; called by muse, mutect2, varscan2
- DACT2 | c.585C>T p.G195= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs918517391, COSV64693413; called by muse, varscan2
- OR52D1 | c.885C>A p.L295= | Silent (SNP) | VAF 55/373 reads (15%) | called by muse, mutect2, varscan2
- FUZ | c.492+74del | Intron (DEL) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- KDM4D | c.*18A>G | 3'UTR (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- RBSN | c.-79A>G | 5'UTR (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- SHF | c.304-9601G>A | Intron (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- ZNF69 | c.-72del | 5'UTR (DEL) | VAF 4/32 reads (13%) | called by mutect2, varscan2
